Gene-level copy-number profile of tumor specimen TCGA-4X-A9FD-01A from TCGA case TCGA-4X-A9FD, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.7 years (15,968 days).
Specimen TCGA-4X-A9FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.78b4cba1-70c3-4f38-bcce-b3d16d6c58e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4X-A9FD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38e40989-59ac-431c-9314-92308247db09

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 24,074; copy number 4: 26,080; copy number 5: 9,369; copy number 7: 287.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4X-A9FD-01A-11D-A422-01): tumor purity 0.33, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,369 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–38,253,429, 669 genes, copy number 5 (broad region; genes not listed).
- chr7:38,322,446–159,233,377, 2,335 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–50,235,310, 100 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
